Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8485, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8485-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED] Case ID	Gross Description	[REDACTED] Microscopic Description	Diagnosis Details
[REDACTED]			

[page 2 of 3]
Comments	Formatted Path Report
	STOMACH TISSUE CHECKLIST Specimen type: Excision of tumor Tumor site: Fundus Tumor size: 9.5 x 6 x 1.5 cm Tumor features: Ulcerated Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Adjacent structures (specify) - Esophagus; lesser omentum Lymph nodes: 7/13 positive for metastasis (Intraabdominal 7/13) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified

	ID

[page 3 of 3]
Excision date

Laterality

Source: NCI Genomic Data Commons file 42fb7549-6aa7-4bb4-8ff4-3aa1db0d1a6c (TCGA-BR-8485.D2272CED-29FC-4DA0-9DE3-CFDF0E2CD899.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).